Gene-level copy-number profile of tumor specimen TCGA-KF-A41W-01A from TCGA case TCGA-KF-A41W, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 71.1 years (25,969 days).
Specimen TCGA-KF-A41W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.5f38663f-a033-4cd1-9962-33b2c23c3f65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KF-A41W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/22a0d2c0-ab4b-47cd-843a-ab8cdb910dba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 4,495; copy number 2: 25,278; copy number 3: 22,491; copy number 4: 6,222; copy number 5: 683; copy number 6: 545; copy number 15: 5; copy number 51: 27; copy number 52: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KF-A41W-01A-11D-A24M-01): tumor purity 0.58, ploidy 2.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:233,059,967–233,207,903, 2 genes (within-gene range 0–1): INPP5D, RN7SL32P.
- chr13:46,553,168–46,753,040, 2 genes (within-gene range 0–3): LRCH1, AL359880.1.
- chr13:47,307,082–47,307,301, 1 gene: GNG5P5.
- chr13:48,232,612–49,691,486, 33 genes: ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL.
- chr13:50,361,410–50,910,764, 5 genes (within-gene range 0–3): RPL34P26, AL158195.1, DLEU7, RNA5SP28, RNASEH2B-AS1.
- chr13:51,082,119–51,767,709, 18 genes (within-gene range 0–2): C13orf42, RPL5P31, AL157817.1, PRELID3BP2, FAM124A, SERPINE3, MIR5693, INTS6, INTS6-AS1, RPS4XP16, RN7SL320P, SNRPGP11, MIR4703, RNU6-65P, WDFY2, RNY1P6, RN7SL413P, ATP5PBP1.
- chr13:55,999,200–56,216,942, 3 genes: HNF4GP1, AL138997.1, SPATA2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,263 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,395,943–95,782,342, 376 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:22,445,673–23,521,202, 15 genes, copy number 5: LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1.
- chr11:24,496,970–25,082,638, 2 genes, copy number 5 (within-gene range 3–5): LUZP2, AC115990.1.
- chr13:112,690,329–113,816,995, 35 genes, copy number 15–52 (within-gene range 2–52): ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B.
- chr15:19,878,555–36,252,257, 545 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr15:83,112,738–83,207,823, 1 gene, copy number 5 (within-gene range 1–5): HDGFL3.
- chr15:83,179,182–95,169,864, 288 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr15:99,098,217–99,135,593, 1 gene, copy number 5 (within-gene range 1–5): SYNM.

Autosomal genes at a single copy (total copy number 1): 4,320. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
